Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GF, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GF-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: poor differentiated adenocarcinoma

Anatomic site with laterality: distal esophagus

Tumor size: diameter 7,0 cm

Lymph node status: 7 positive lymph nodes

Any comments or amendments: irradical resection

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Esophagus, distal third
C15.5

W 1/29/14

Also submitting Metastatic tumor

Source: NCI Genomic Data Commons file 1514448e-2cd2-4f0d-8053-bfc5e359df5b (TCGA-2H-A9GF.AF2760CD-D9B8-4FBC-9EF7-07CC642646DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).